Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9Q0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9Q0-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Left kidney, partial nephrectomy: Papillary renal cell carcinoma, 4.8 cm; see comment.
- B. Left kidney, base margin, biopsy: Medullary renal tissue, no tumor seen.
- C. Left kidney, lower renal lesion, excision:
1. Fibrous capsule with chronic inflammation, no tumor seen.
2. Perinephric fat, no tumor seen.
- D. Left kidney, perihilar tissue, partial nephrectomy: Adipose tissue, no tumor seen.
- E. Left kidney, perinephric fat, partial nephrectomy: Adipose tissue, no tumor seen.
- F. Left kidney, cyst wall, biopsy: Necrotic debris, no tumor seen.
- G. Left kidney, lower renal lesion, excision: Portion of epithelial-lined cyst with necrotic debris, no tumor seen.

COMMENT:

The diagnosis was discussed with [REDACTED]

Kidney Tumor Synoptic Comment

- Histologic type: Renal cell carcinoma, papillary (chromophil) type.
- Grade: 3.
- Maximum tumor diameter: 4.8 cm.
- Site within kidney: Upper pole.
- Renal pelvis: Not present.
- Ureter: Not present.

ICD-O-3
Carcinoma, papillary renal
cell (Chromophil) 8260/3
Site @ Kidney NOS C64.9
9/30/14

[page 2 of 3]
[REDACTED]

-Renal sinus: Not present.
-Hilar renal veins: Not present.
-Intrarenal veins and lymphatics: Normal, no tumor.
-Adrenal gland: Not present.
-Capsule/perirenal fat: Tumor does not penetrate capsule.
-Hilar lymph nodes (number positive/number of nodes): No lymph nodes present.
-Resection margins: Negative.
-Proximity to nearest margin: 0.1 cm.
-Stage: pT1NXMX.
-Additional comments: The majority of the tumor demonstrates Fuhrman grade 2 nuclei. However, occasional grade 3 nuclei are seen, rendering a final designation of grade 3.

Specimen(s) Received

A: Left renal mass (FS)
B: Base margin (FS)
C: Lower renal lesion (FS)
D: Perihilar tissue
E: Perinephric fat
F: Cyst wall
G: Renal lesion

Intraoperative Diagnosis

FS1 (A) Left renal mass, partial nephrectomy: Renal cell carcinoma with papillary features. [REDACTED]
FS2 (B) Kidney, base margin, biopsy: Benign renal tissue. [REDACTED]
FS3 (C) Lower renal lesion, excision: Fibrous wall with chronic inflammation and hemosiderin; no tumor seen. [REDACTED]

Clinical History

The patient is a [REDACTED]-year-old man who undergoes resection of a complex renal cyst in the left upper pole.

Gross Description

The specimen is received in seven parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh from the Operating Room. Parts D-G are received in formalin.

Part A, additionally labeled "left renal mass FS," consists of a pole of kidney measuring 5.0 x 4.5 x 3.0 cm, with attached perinephric fat, 7.0 x 6.8 x 5.5 cm, and weighing 181 gm. The kidney contains a well-encapsulated, cystic lesion measuring 4.8 x 4.2 x 2.0 cm, and containing friable, brown-yellow material. The capsule appears intact, is white and fibrous, and ranges from 0.2 to 0.4 cm. The mass extends to 0.1 cm of the surgical resection margin and does not appear to extend through the capsule at any point, or into the perinephric fat. The small rim of non-neoplastic renal tissue is red-brown and grossly unremarkable. No calyceal or collecting system tissue is seen. The perinephric fat surrounding the kidney is yellow-tan and is received partially dissected from the kidney, such that the relationship of the tumor to the surgical plane (perinephric fat margin) cannot be adequately determined. Extensive examination of the perinephric fat reveals no focal nodules or lymph nodes. The kidney resection margin is inked black. A representative section of the cystic mass is submitted for frozen section 1, with the frozen section remnant submitted in cassette A1. Additional representative sections are submitted as follows:

Cassettes A2-A3: Tumor with resection margin.
Cassettes A4-A5: Additional tumor with capsule.
Cassettes A6-A7: Perinephric fat.

Part B, additionally labeled "base margin FS," consists of a single, irregularly shaped fragment of pink-brown tissue measuring 1.2 x 0.7 x 0.4 cm in greatest dimension. The entire specimen is frozen for frozen section 2, with the remnant submitted in cassette B1.

[page 3 of 3]
[REDACTED]

Part C, additionally labeled "lower renal lesion FS," consists of a cup-shaped piece of fatty tissue weighing 157 gm and measuring 5.6 x 4.5 x 2.8 cm in greatest dimension. The specimen consists mostly of unremarkable, pink-yellow-brown, fatty tissue. The concave area, presumably representing the side nearest the kidney, contains a central cup-shaped, fibrous, yellow-orange lesion, consistent with cyst wall, measuring 3.0 x 2.5 x 1.2 cm in greatest dimension. This lesion is located 2.0 cm to the nearest surgical margin. A representative section of the cyst wall is submitted for frozen section 3, with the frozen section remnant submitted in cassette C1. The remaining cyst wall is entirely submitted in cassettes C2-C7. A single section corresponding the nearest approach to the outer margin is submitted in cassette C8.

Part D, additionally labeled "peri-hilar tissue," consists of a single, irregularly shaped fragment of yellow-tan, fatty tissue measuring 3.8 x 3.0 x 0.3 cm in greatest dimension. The outside aspect is inked, and the specimen is entirely submitted in cassettes D1-D4.

Part E, additionally labeled "perinephric fat," consists of multiple, irregularly shaped fragments of yellow-tan, adipose tissue measuring 9.0 x 6.0 x 3.5 cm in aggregate. The specimen is examined, and only a single firm, fibrous area, measuring 0.3 cm in greatest dimension, is identified. The specimen is unremarkable. Representative sections are submitted in cassettes E1-E2, with the fibrous lesion in E1.

Part F, additionally labeled "cyst wall," consists of a single, irregularly shaped fragment of firm, brown-tan tissue measuring 1.5 x 0.5 x 0.2 cm in aggregate. The specimen is entirely submitted in cassette F1.

Part G, additionally labeled "lower renal lesion," consists of four, irregularly shaped fragments of brown-pink, friable, soft tissue measuring 2.6 x 1.8 x 0.4 cm in greatest dimension. The specimen is entirely submitted in cassettes G1-G2.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist
Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 38e989d0-4aea-4b66-b8f7-d81cb9f1bc31 (TCGA-UZ-A9Q0.1D0AA06F-78C1-49F9-9C30-088CE2F4F5B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).